Somatic mutation profile of tumor specimen MMRF_2670_1_BM_CD138pos (aliquot MMRF_2670_1_BM_CD138pos_T1_KHS5U_L13788) from MMRF case MMRF_2670, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.4 years (23,142 days).
Specimen MMRF_2670_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37fcc432-6b1c-49cd-87d5-d9f9d1183f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2670_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2670_1_PB_WBC_C3_KHS5U_L13789; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1091d48-6a37-4c4f-b82b-d22a4511c5e6

The open-access MAF lists 121 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 36, Missense Mutation 34, Intron 18, Silent 12, 5'UTR 6, 5'Flank 4, 3'Flank 3, RNA 3, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.2521A>G p.S841G | Missense Mutation (SNP) | VAF 248/799 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs747590381; called by muse, mutect2, varscan2
- ANKRD30B | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 222/394 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs752127097, COSV62814186, COSV62825406; called by muse, mutect2, varscan2
- ANO3 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 220/684 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200440564; called by muse, mutect2, varscan2
- CDH11 | c.2230G>A p.G744S | Missense Mutation (SNP) | VAF 289/703 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs374889086, COSV51753347, COSV51767545; called by muse, mutect2, varscan2
- CDH23 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 257/692 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs370747698; called by muse, mutect2, varscan2
- DEAF1 | c.56_82del p.V19_A27del | In Frame Del (DEL) | VAF 34/75 reads (45%) | catalogued as rs768085739; ClinVar: uncertain significance; called by mutect2, pindel*, varscan2
- DLGAP4 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 153/338 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs748450222, COSV59419375; called by muse, mutect2, varscan2
- FREM2 | c.4064G>A p.R1355Q | Missense Mutation (SNP) | VAF 170/433 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs753133994, COSV54836585; called by muse, mutect2, varscan2
- IGHJ3 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 258/290 reads (89%) | PolyPhen benign (0.003); catalogued as rs190698203; called by muse, varscan2
- IGLV3-1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 236/291 reads (81%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs61731694; called by muse, mutect2, varscan2
- IGLV3-1 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 212/269 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs375047302; called by muse, mutect2
- MAN2B2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs746731421, COSV53453581; called by muse, mutect2, varscan2
- MRM2 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 462/746 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs201350897; called by muse, mutect2, varscan2
- NFKB2 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 30/276 reads (11%) | catalogued as rs747113965; called by muse, mutect2, varscan2
- NTN4 | c.1180+1G>A p.X394_splice | Splice Site (SNP) | VAF 69/158 reads (44%) | catalogued as rs1290216668, COSV100643670; called by muse, mutect2, varscan2
- PDE6A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768596256, COSV54926143; ClinVar: uncertain significance; called by muse, mutect2
- PTPRF | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 162/404 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1160984093, COSV100741219; called by muse, mutect2, varscan2
- SOX17 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52027311; called by muse, mutect2
- SPEG | c.5702dup p.E1902Rfs*24 | Frame Shift Ins (INS) | VAF 118/294 reads (40%) | catalogued as rs765267670; called by mutect2, varscan2
- DCAF7 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 412/1009 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DNAH12 | c.6591A>C p.R2197S (on ENST00000351747; = p.R2216S on NM_001366028.2) | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- H1-0 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 123/595 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- HCFC1 | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 114/1011 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.137); called by mutect2, varscan2
- INSL4 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ISL1 | c.210T>A p.D70E | Missense Mutation (SNP) | VAF 167/389 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MORC1 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PCDH8 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 348/754 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLB1 | c.1823C>G p.T608S | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PRKD2 | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 200/687 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SEMA3C | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2
- SENP2 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 287/1249 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SERPINE2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 299/719 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SLITRK5 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 289/712 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TRIL | c.1607C>G p.P536R | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- UHRF2 | c.2173A>G p.K725E | Missense Mutation (SNP) | VAF 194/403 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- XPNPEP3 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 58/483 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- XPO4 | c.2633T>A p.L878* | Nonsense Mutation (SNP) | VAF 73/187 reads (39%) | called by muse, varscan2
- ZBED6 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 381/835 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ZMPSTE24 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 48/465 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- ANKRD28 | c.381A>G p.V127= | Silent (SNP) | VAF 299/1104 reads (27%) | catalogued as rs1016674400; called by muse, mutect2, varscan2
- CADPS | c.3072C>T p.N1024= | Silent (SNP) | VAF 240/796 reads (30%) | catalogued as rs1043545485; called by muse, mutect2, varscan2
- CSNK1G3 | c.942A>G p.R314= | Silent (SNP) | VAF 99/223 reads (44%) | called by muse, mutect2, varscan2
- GPI | c.414C>T p.S138= | Silent (SNP) | VAF 38/627 reads (6%) | catalogued as rs779166692; called by muse, mutect2
- MED23 | c.180C>T p.I60= | Silent (SNP) | VAF 144/321 reads (45%) | called by muse, mutect2, varscan2
- PCDHA12 | c.810C>T p.D270= | Silent (SNP) | VAF 225/550 reads (41%) | catalogued as rs1227830598, COSV100250622; called by muse, mutect2, varscan2
- PRL | c.525C>T p.Y175= | Silent (SNP) | VAF 27/410 reads (7%) | catalogued as rs755807577; called by muse, mutect2
- SLC2A8 | c.1053G>A p.S351= | Silent (SNP) | VAF 180/410 reads (44%) | catalogued as rs754821992, COSV64895366; called by muse, mutect2, varscan2
- SLC43A2 | c.348G>A p.R116= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as COSV56771390; called by muse, mutect2, varscan2
- SP3 | c.351A>G p.T117= | Silent (SNP) | VAF 142/325 reads (44%) | called by muse, mutect2, varscan2
- SPATA20 | c.2322C>T p.I774= (on ENST00000356488 / NM_001258372.1; = p.I790= on NM_022827.4) | Silent (SNP) | VAF 126/284 reads (44%) | catalogued as rs1394867705; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1026G>A p.L342= | Silent (SNP) | VAF 48/457 reads (11%) | called by muse, varscan2
- ACTB | c.-6C>T | 5'UTR (SNP) | VAF 155/264 reads (59%) | catalogued as rs201298672, COSV59320416; called by muse, mutect2
- AFAP1 | c.*1364T>C | 3'UTR (SNP) | VAF 256/286 reads (90%) | catalogued as rs999616517; called by muse, mutect2, varscan2
- AHCYL1 | c.*717A>C | 3'UTR (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- AL356585.2 | n.2021C>G | RNA (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.3905-51C>T | Intron (SNP) | VAF 68/313 reads (22%) | called by muse, mutect2, varscan2
- ASGR1 | c.702-35G>A | Intron (SNP) | VAF 162/395 reads (41%) | catalogued as rs764780656, COSV52648326; called by muse, mutect2, varscan2
- ASH1L | chr1:155563098 T>G | 5'Flank (SNP) | VAF 132/529 reads (25%) | called by muse, varscan2
- B3GALT6 | c.*1337G>T | 3'UTR (SNP) | VAF 113/1086 reads (10%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021362 T>A | 5'Flank (SNP) | VAF 206/491 reads (42%) | called by muse, varscan2
- C15orf61 | c.346+28G>A | Intron (SNP) | VAF 59/552 reads (11%) | called by muse, mutect2, varscan2
- C21orf62 | c.*2774dup | 3'UTR (INS) | VAF 202/499 reads (40%) | called by mutect2, pindel, varscan2
- C2CD2L | c.*1578_*1580dup | 3'UTR (INS) | VAF 34/215 reads (16%) | called by mutect2, pindel, varscan2
- C4orf33 | c.181+62A>G | Intron (SNP) | VAF 125/138 reads (91%) | called by muse, mutect2, varscan2
- CCNC | chr6:99568684 C>A | 5'Flank (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- CDC42SE1 | c.-63A>G | 5'UTR (SNP) | VAF 51/463 reads (11%) | called by muse, mutect2, varscan2
- CDK17 | c.*120T>G | 3'UTR (SNP) | VAF 161/385 reads (42%) | called by muse, mutect2, varscan2
- CTNND1 | c.*74C>T | 3'UTR (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- EHF | c.*581C>T | 3'UTR (SNP) | VAF 96/178 reads (54%) | called by muse, mutect2, varscan2
- EML6 | c.2052-19T>G | Intron (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- GPR68 | c.-111C>T | 5'UTR (SNP) | VAF 264/556 reads (47%) | catalogued as rs904161179, COSV99473573; called by muse, mutect2, varscan2
- GSTM3 | c.*1581A>C | 3'UTR (SNP) | VAF 129/281 reads (46%) | called by muse, mutect2, varscan2
- ICE2 | c.1125+1024C>G | Intron (SNP) | VAF 57/243 reads (23%) | called by muse, mutect2, varscan2
- IQUB | c.*76G>A | 3'UTR (SNP) | VAF 431/743 reads (58%) | called by muse, mutect2, varscan2
- ITPRIPL1 | chr2:96328499 C>T | 3'Flank (SNP) | VAF 58/127 reads (46%) | called by muse, mutect2, varscan2
- KCNJ12 | c.*90C>A | 3'UTR (SNP) | VAF 50/258 reads (19%) | called by muse, mutect2
- KDSR | c.*3446G>A | 3'UTR (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- KIF3B | c.*1849T>C | 3'UTR (SNP) | VAF 92/194 reads (47%) | called by muse, mutect2, varscan2
- KLHL2 | c.*622C>A | 3'UTR (SNP) | VAF 112/259 reads (43%) | called by muse, mutect2, varscan2
- KMT5B | c.*629A>G | 3'UTR (SNP) | VAF 95/277 reads (34%) | catalogued as rs1000986994; called by muse, mutect2, varscan2
- LANCL3 | c.1103+936C>T | Intron (SNP) | VAF 335/421 reads (80%) | catalogued as rs1301616027; called by muse, mutect2, varscan2
- LRTM1 | c.*127_*131del | 3'UTR (DEL) | VAF 27/244 reads (11%) | catalogued as rs781760115; called by pindel, varscan2
- MAGEA9B | c.*56G>T | 3'UTR (SNP) | VAF 80/1085 reads (7%) | called by muse, mutect2
- MAP7 | c.*376T>A | 3'UTR (SNP) | VAF 95/230 reads (41%) | catalogued as rs563288179, COSV63420446; called by muse, mutect2, varscan2
- MINPP1 | c.*708G>C | 3'UTR (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- MIR137 | chr1:98045175 G>T | 3'Flank (SNP) | VAF 246/577 reads (43%) | called by muse, mutect2, varscan2
- MIR5195 | n.25G>A | RNA (SNP) | VAF 137/560 reads (24%) | called by muse, varscan2
- MIR5195 | chr14:106851224 G>A | 5'Flank (SNP) | VAF 663/1125 reads (59%) | catalogued as rs544431037; called by muse, mutect2, varscan2
- MSLNL | c.503+14G>T | Intron (SNP) | VAF 64/169 reads (38%) | called by muse, mutect2, varscan2
- MYO16 | c.2806+1867C>G | Intron (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- NACA | c.70+4636del | Intron (DEL) | VAF 103/287 reads (36%) | called by mutect2, pindel, varscan2
- NANOGNB | c.-68C>T | 5'UTR (SNP) | VAF 22/722 reads (3%) | called by muse, mutect2
- NSD2 | c.1881+5424T>A | Intron (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.393C>T | RNA (SNP) | VAF 75/165 reads (45%) | catalogued as rs777242556; called by muse, mutect2, varscan2
- PCNX2 | c.3946+25C>T | Intron (SNP) | VAF 189/500 reads (38%) | called by muse, varscan2
- PLEKHG5 | c.1392+49C>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- PRDM5 | c.300+15376A>T | Intron (SNP) | VAF 50/271 reads (18%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*2238G>A | 3'UTR (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- RASSF8 | c.*584_*585del | 3'UTR (DEL) | VAF 14/168 reads (8%) | called by mutect2, pindel
- RBBP6 | c.*312_*323del | 3'UTR (DEL) | VAF 42/107 reads (39%) | called by mutect2, pindel, varscan2
- RBM39 | c.52-18_52-16del | Intron (DEL) | VAF 86/202 reads (43%) | catalogued as rs1192864865; called by pindel, varscan2
- RET | c.*651A>T | 3'UTR (SNP) | VAF 119/226 reads (53%) | catalogued as rs1257867867; called by muse, mutect2, varscan2
- RPS15A | c.*116T>G | 3'UTR (SNP) | VAF 223/553 reads (40%) | called by muse, mutect2, varscan2
- SART1 | c.372-102G>A | Intron (SNP) | VAF 100/231 reads (43%) | called by muse, mutect2, varscan2
- SEMA3D | c.*3670G>C | 3'UTR (SNP) | VAF 54/191 reads (28%) | catalogued as rs1489618909; called by muse, mutect2, varscan2
- SFRP2 | c.*394G>A | 3'UTR (SNP) | VAF 101/223 reads (45%) | called by muse, mutect2, varscan2
- SKP1 | c.*220_*263del | 3'UTR (DEL) | VAF 37/145 reads (26%) | called by mutect2, pindel, varscan2
- SLC26A4 | c.*642T>C | 3'UTR (SNP) | VAF 16/343 reads (5%) | catalogued as rs1045374248; called by muse, mutect2
- SLIT2 | c.-383A>G | 5'UTR (SNP) | VAF 52/890 reads (6%) | called by muse, mutect2
- SNTB1 | c.*2771G>A | 3'UTR (SNP) | VAF 128/297 reads (43%) | called by muse, mutect2, varscan2
- SP3 | c.*2438A>T | 3'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- SUZ12 | c.*1154T>A | 3'UTR (SNP) | VAF 105/261 reads (40%) | called by muse, mutect2, varscan2
- TERT | c.-34C>T | 5'UTR (SNP) | VAF 11/25 reads (44%) | catalogued as rs1009085379; called by muse, mutect2, varscan2
- TMSB4X | c.-16-198A>G | Intron (SNP) | VAF 126/145 reads (87%) | called by muse, mutect2, varscan2
- TNFSF10 | c.*164C>A | 3'UTR (SNP) | VAF 78/262 reads (30%) | called by muse, mutect2, varscan2
- TNS1 | c.*411G>A | 3'UTR (SNP) | VAF 140/346 reads (40%) | called by muse, mutect2
- TRPM3 | c.1154+7644G>T | Intron (SNP) | VAF 28/529 reads (5%) | called by muse, mutect2
- VAX1 | chr10:117131706 C>T | 3'Flank (SNP) | VAF 191/462 reads (41%) | called by muse, mutect2, varscan2
- WHAMM | c.*1018C>T | 3'UTR (SNP) | VAF 45/424 reads (11%) | catalogued as rs1418406309; called by muse, mutect2, varscan2
- ZBTB47 | c.*160G>A | 3'UTR (SNP) | VAF 46/264 reads (17%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1979A>G | 3'UTR (SNP) | VAF 37/53 reads (70%) | called by muse, mutect2, varscan2
